Somatic mutation profile of tumor specimen TARGET-20-PARYVW-04A (aliquot TARGET-20-PARYVW-04A-02D) from TARGET case TARGET-20-PARYVW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (664 days).
Specimen TARGET-20-PARYVW-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aaad83b-d492-4343-a531-99e9f7d521d8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARYVW-14A (Bone Marrow Normal), aliquot TARGET-20-PARYVW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8638eb7f-08a0-4e04-8d3a-36826816cb72

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBFA2T2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 126/223 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV60073292; called by muse, mutect2, varscan2
